Gene-level copy-number profile of tumor specimen TCGA-HD-A6I0-01A from TCGA case TCGA-HD-A6I0, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G1; Age at diagnosis: 56.1 years (20,491 days).
Specimen TCGA-HD-A6I0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.ce25ff73-eb5a-48b6-8e1d-1250522ecfdb.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HD-A6I0-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9edd8439-3046-4a59-8230-2db6329bfe5f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 23; copy number 1: 2,607; copy number 2: 45,424; copy number 3: 9,461; copy number 4: 2,305.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HD-A6I0-01A-11D-A31K-01): tumor purity 0.57, ploidy 2.27, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 22 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:132,685,224–132,816,896, 1 gene (within-gene range 0–3): AC010974.2.
- chr3:60,616,822–60,618,079, 2 genes: AC104164.2, MIR548BB.
- chr9:21,802,636–22,824,213, 17 genes: MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239.
- chr9:22,747,700–22,768,316, 2 genes: CLIC4P1, AC017067.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 187. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
